Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A5UL, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A5UL-06A (Metastatic).

Gross Description: There is a fatty tissue fragment with black metastatic nodes up to 4 cm in size.

Microscopic Description: Malignant melanoma metastasis in the examined lymph node.

Diagnosis Details: Tumor Features: Indeterminate, Tumor Extent: Other, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments: Patient has a history of the malignant melanoma of the skin of the anterior chest wall. He underwent surgery on Currently patient is diagnosed with tumor progression: metastases in the axillary lymph nodes. On patient underwent surgery procedure: axillary lymph node dissection. Despite progression, initially established stage II (T3N0M0) does not change.

Formatted Path Reports: LYMPH NODE CHECKLIST

Specimen type: Metastatic neoplasm, malignant melanoma of the lymph node

Tumor size: 4 cm

Margins: Uninvolved

Diagnosis details: Breslow thickness=4, Clark level=Unknown,

Comments: Patient has a history of the malignant melanoma of the skin of the anterior chest wall. He underwent surgery on Currently patient is diagnosed with tumor progression: metastases in the axillary lymph nodes. On patient underwent surgery procedure: axillary lymph node dissection. Despite progression, initially established stage II (T3N0M0) does not change.

ICD-O-3
Melanoma, malignant NOS
8720/3
Site: Lymph Nodes, axilla
C77.3
J10 2/19/13

ICDPA Discrepancy		☒
Prior Malignancy History: Melanoma - Chest Wall	☒	☐

Source: NCI Genomic Data Commons file 09d49b96-5d81-495d-93ef-1c8f2a105046 (TCGA-EB-A5UL.4AD68ABB-FE4F-45FA-9248-CEFF249ABB75.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).